Somatic mutation profile of tumor specimen C3L-07542-01 (aliquot CPT0477350006) from CPTAC case C3L-07542, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.5 years (27,220 days).
Specimen C3L-07542-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b8ee408-5728-4872-96d1-9910b51772be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07542-31 (Blood Derived Normal), aliquot CPT0475610004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09260d7e-eb4f-4893-ba81-677603a5c140

The open-access MAF lists 1,819 somatic variants for this specimen: 1,361 protein-altering or splice-affecting, 393 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 909, Silent 393, Frame Shift Del 297, Frame Shift Ins 87, Nonsense Mutation 38, Intron 27, 3'UTR 12, In Frame Del 10, 5'Flank 10, Splice Region 8, Splice Site 8, RNA 6.

Variants (750 of 1,819; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 30/192 reads (16%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ASXL1 | c.1933_1934del p.G645Wfs*12 | Frame Shift Del (DEL) | VAF 101/602 reads (17%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 71/401 reads (18%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.5073dup p.W1692Mfs*3 | Frame Shift Ins (INS) | VAF 49/244 reads (20%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 40/246 reads (16%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 66/297 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- ERBB3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 80/362 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs931676601, COSV57250012; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 171/466 reads (37%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 145/658 reads (22%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KCNJ2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473373, CM066888, COSV54664479; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 50/260 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 134/469 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TCTN2 | c.76dup p.D26Gfs*52 | Frame Shift Ins (INS) | VAF 78/400 reads (20%) | catalogued as rs863225222; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.1964del p.P655Rfs*4 (on ENST00000326724 / NM_001080395.3; = p.P552Rfs*4 on NM_004920.2) | Frame Shift Del (DEL) | VAF 127/766 reads (17%) | catalogued as rs748280166, COSV58368179; called by mutect2, pindel, varscan2
- ABCA4 | c.6250G>A p.A2084T | Missense Mutation (SNP) | VAF 75/379 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250914690, COSV64671514, COSV64677755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 66/343 reads (19%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCC1 | c.3925G>A p.V1309I | Missense Mutation (SNP) | VAF 113/512 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs759668292; called by muse, mutect2, varscan2
- ABCC3 | c.2060T>C p.M687T | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.08); catalogued as rs770297091; called by muse, mutect2, varscan2
- ABCC8 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs199732808, COSV100217541; called by muse, mutect2, varscan2
- AC116366.2 | c.-169G>T | Splice Region (SNP) | VAF 60/297 reads (20%) | catalogued as COSV55378036; called by muse, mutect2, varscan2
- ACAN | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 110/487 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs747278844; called by muse, mutect2, varscan2
- ACAP1 | c.391del p.A131Lfs*8 | Frame Shift Del (DEL) | VAF 106/588 reads (18%) | catalogued as COSV50134051; called by mutect2, pindel, varscan2
- ACSM1 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54638199; called by muse, varscan2
- ACVR1B | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766927234; called by muse, mutect2, varscan2
- ADAM23 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1367668000; called by muse, mutect2, varscan2
- ADAM29 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 70/453 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746641739, COSV63663321; called by muse, mutect2, varscan2
- ADAMTS10 | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 132/402 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782568976; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- ADCY8 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1403776150, COSV99651382; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58445481; called by muse, varscan2
- ADD1 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 84/450 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766033361, COSV53267490; called by muse, mutect2, varscan2
- ADGRB2 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 112/621 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs746636296, COSV57079132, COSV99925780; called by muse, mutect2, varscan2
- ADGRV1 | c.16395dup p.V5466Cfs*5 | Frame Shift Ins (INS) | VAF 40/192 reads (21%) | catalogued as rs1166500471; called by mutect2, varscan2
- ADRB1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 105/521 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65167628; called by muse, mutect2, varscan2
- AFAP1 | c.886T>C p.C296R | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.446); catalogued as rs747193934; called by muse, varscan2
- AFDN | c.509del p.K170Rfs*53 | Frame Shift Del (DEL) | VAF 60/355 reads (17%) | catalogued as rs1431558072; called by mutect2, pindel, varscan2
- AFF2 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV100648834; called by muse, mutect2, varscan2
- AGBL5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 58/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747996062, COSV59938069; called by muse, mutect2, varscan2
- AHDC1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 112/566 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as rs1312950480; called by muse, mutect2, varscan2
- AHNAK2 | c.12352del p.D4118Tfs*9 | Frame Shift Del (DEL) | VAF 106/678 reads (16%) | catalogued as COSV60933710; called by mutect2, pindel, varscan2
- AIFM3 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 94/447 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs986397770, COSV59001809; called by muse, mutect2, varscan2
- AKAP11 | c.2479_2480del p.E827Rfs*19 | Frame Shift Del (DEL) | VAF 52/357 reads (15%) | catalogued as rs1161332807; called by pindel, varscan2
- AKAP13 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 108/465 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs138265569; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 70/304 reads (23%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AL358113.1 | c.3792G>A p.T1264= | Splice Region (SNP) | VAF 64/299 reads (21%) | catalogued as rs771190188, COSV55262709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX12B | c.1795A>G p.M599V | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1301249773; called by muse, mutect2
- ALPK1 | c.1456dup p.T486Nfs*40 | Frame Shift Ins (INS) | VAF 76/386 reads (20%) | catalogued as rs1560686124; called by mutect2, pindel, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 85/447 reads (19%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMER2 | c.1186T>G p.C396G | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV63436797; called by muse, mutect2, varscan2
- ANKRD17 | c.3155C>A p.P1052H | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1328218647; called by muse, mutect2, varscan2
- ANKRD54 | c.822A>C p.K274N | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs748498656, COSV99316557; called by muse, mutect2, varscan2
- APPL2 | c.633del p.F211Lfs*28 | Frame Shift Del (DEL) | VAF 40/235 reads (17%) | catalogued as COSV51591248; called by mutect2, pindel, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 73/420 reads (17%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARHGAP32 | c.3053del p.P1018Lfs*28 (on ENST00000310343 / NM_001378025.1; = p.P669Lfs*28 on NM_014715.4) | Frame Shift Del (DEL) | VAF 53/297 reads (18%) | catalogued as COSV59843506; called by mutect2, pindel, varscan2
- ARHGEF33 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 112/564 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV101289808; called by muse, mutect2, varscan2
- ARID3A | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 265/703 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs576049092; called by muse, mutect2, varscan2
- ARID4A | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs762052890; called by muse, mutect2, varscan2
- ARMC1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs768173964; called by muse, mutect2, varscan2
- ARSI | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 92/484 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs1387998500; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 61/347 reads (18%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASB2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 112/522 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1203361632; called by muse, mutect2, varscan2
- ATAD1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57757222; called by muse, varscan2
- ATP10A | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63515667; called by muse, mutect2, varscan2
- ATP8B1 | c.2497C>T p.R833W | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1406196327; called by muse, mutect2, varscan2
- B3GALNT2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 101/416 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.328); catalogued as rs962461243; called by muse, mutect2, varscan2
- BAIAP3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs142556073; called by muse, mutect2, varscan2
- BARHL1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs376566705; called by muse, mutect2, varscan2
- BCKDK | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV99570569; called by muse, mutect2, varscan2
- BDH1 | c.685del p.L229Wfs*3 | Frame Shift Del (DEL) | VAF 139/724 reads (19%) | catalogued as rs1002260866; called by mutect2, pindel, varscan2
- BDNF | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs758274361; called by muse, mutect2, varscan2
- BEAN1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 60/330 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV55277681; called by muse, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 79/508 reads (16%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BICD2 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 94/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774714446, COSV63548838; called by muse, mutect2, varscan2
- BICRA | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 295/782 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.421); catalogued as rs765520797; called by muse, mutect2, varscan2
- BNC2 | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 81/399 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV66163181; called by muse, mutect2, varscan2
- BNC2 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs181797373, COSV66158197; called by muse, mutect2, varscan2
- BNIP5 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.09); catalogued as rs771516238, COSV101465219; called by muse, mutect2, varscan2
- BOLA1 | c.411del p.*138Efs*24 | Frame Shift Del (DEL) | VAF 56/276 reads (20%) | catalogued as rs781977939; called by mutect2, varscan2
- BOLL | c.160del p.S54Pfs*6 | Frame Shift Del (DEL) | VAF 33/233 reads (14%) | catalogued as rs1428711101, COSV56578902; called by mutect2, pindel, varscan2
- BPNT2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750461430, COSV52909045; called by muse, mutect2, varscan2
- BPTF | c.3895C>T p.R1299W | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs773960660; called by muse, mutect2, varscan2
- BRI3BP | c.45_47dup p.L25dup | In Frame Ins (INS) | VAF 76/292 reads (26%) | catalogued as rs1555215957; called by pindel, varscan2
- BSG | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 120/696 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761119905; called by muse, mutect2, varscan2
- BST2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 147/386 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs764134970; called by muse, mutect2, varscan2
- BTF3 | c.386C>T p.A129V (on ENST00000380591 / NM_001037637.1; = p.A85V on NM_001207.4) | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs1161723411; called by muse, mutect2
- BUB1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs368925928; called by muse, mutect2, varscan2
- C19orf57 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 101/650 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs372991147, COSV100694620; called by muse, mutect2, varscan2
- C3 | c.2670del p.K891Sfs*13 | Frame Shift Del (DEL) | VAF 96/614 reads (16%) | catalogued as rs750770711, COSV99837243; called by mutect2, pindel, varscan2
- C6orf52 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs369274162; called by muse, varscan2
- CA5B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs766858791, COSV59417187; called by muse, mutect2, varscan2
- CAMSAP3 | c.3646G>A p.A1216T | Missense Mutation (SNP) | VAF 105/609 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV50337370; called by muse, mutect2, varscan2
- CAPN10 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 119/544 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs1180541746; called by muse, mutect2, varscan2
- CBX7 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 117/564 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.289); catalogued as rs1223729085; called by muse, mutect2, varscan2
- CCDC148 | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs773979843; called by muse, mutect2, varscan2
- CCDC150 | c.3098G>A p.R1033H | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as rs202137904; called by muse, mutect2, varscan2
- CCDC166 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 136/830 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs868964358, COSV72638706; called by muse, mutect2, varscan2
- CCDC168 | c.14326G>A p.V4776I | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs927798070; called by muse, mutect2, varscan2
- CCDC30 | c.1825dup p.R609Kfs*33 (on ENST00000340612; = p.R566Kfs*33 on NM_001080850.3) | Frame Shift Ins (INS) | VAF 78/436 reads (18%) | catalogued as rs1184562488; called by mutect2, pindel, varscan2
- CCDC42 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.527); catalogued as COSV53448405; called by muse, varscan2
- CCDC47 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.672); catalogued as rs369027114; called by muse, mutect2, varscan2
- CCDC60 | c.152del p.K51Rfs*9 | Frame Shift Del (DEL) | VAF 52/291 reads (18%) | catalogued as COSV59545983; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | catalogued as rs747079826; called by mutect2, varscan2
- CCR3 | c.701dup p.Y235Vfs*38 | Frame Shift Ins (INS) | VAF 70/380 reads (18%) | catalogued as rs761073142; called by mutect2, varscan2
- CDC73 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100813910, COSV66467919; called by muse, mutect2, varscan2
- CDH10 | c.322del p.T108Qfs*30 | Frame Shift Del (DEL) | VAF 71/404 reads (18%) | catalogued as rs748395403; called by mutect2, pindel, varscan2
- CDH13 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs375168918; called by muse, mutect2, varscan2
- CDH23 | c.2600del p.P867Lfs*2 | Frame Shift Del (DEL) | VAF 52/319 reads (16%) | catalogued as rs34768093; called by pindel, varscan2
- CDHR5 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 166/833 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374269787; called by muse, mutect2
- CDYL2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 75/331 reads (23%) | catalogued as COSV101629639; called by muse, mutect2, varscan2
- CEACAM6 | c.12del p.S5Qfs*21 | Frame Shift Del (DEL) | VAF 84/528 reads (16%) | catalogued as COSV52268704; called by mutect2, pindel, varscan2
- CELF4 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100611620; called by muse, mutect2, varscan2
- CELSR1 | c.5443G>A p.G1815R | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1282482999, COSV53083158; called by muse, mutect2, varscan2
- CENPJ | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.415); catalogued as COSV67883113; called by muse, mutect2, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 74/461 reads (16%) | catalogued as rs1431118175; called by mutect2, pindel, varscan2
- CFAP46 | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 80/350 reads (23%) | catalogued as rs868499197; called by muse, varscan2
- CHD2 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 79/351 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs368237024; called by muse, mutect2, varscan2
- CHML | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 76/445 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs911830187, COSV59362859; called by muse, mutect2, varscan2
- CHRNA4 | c.1841C>T p.T614M | Missense Mutation (SNP) | VAF 86/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs150905690; called by muse, mutect2, varscan2
- CHSY1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as rs1290220668; called by muse, mutect2, varscan2
- CILP2 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 111/712 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV52278094; called by muse, mutect2, varscan2
- CKMT2 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs776747260; called by muse, mutect2, varscan2
- CLDN5 | c.637_639del p.D213del (on ENST00000618236 / NM_001363066.2; = p.D298del on NM_003277.4) | In Frame Del (DEL) | VAF 53/351 reads (15%) | catalogued as rs749006228; called by mutect2, pindel, varscan2
- CLIP1 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100211305; called by muse, mutect2, varscan2
- CLK3 | c.1028G>A p.R343Q (on ENST00000395066 / NM_001130028.1; = p.R195Q on NM_003992.4) | Missense Mutation (SNP) | VAF 107/430 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1326540251, COSV100776026; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 53/224 reads (24%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSTN3 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as rs369161461; called by muse, mutect2, varscan2
- CNNM3 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs907261063; called by muse, mutect2, varscan2
- CNOT11 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431230517, COSV99179248; called by muse, mutect2, varscan2
- CNTNAP4 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs758195382, COSV56665292; called by muse, mutect2, varscan2
- CNTNAP5 | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs1185746482, COSV101444355; called by muse, mutect2, varscan2
- COL12A1 | c.1405A>G p.S469G | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs1334150715; called by muse, mutect2, varscan2
- COL4A2 | c.4466G>A p.G1489D | Missense Mutation (SNP) | VAF 92/530 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1025762255; called by muse, mutect2, varscan2
- COL5A1 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as rs774849517, COSV65664573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 88/447 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060502252, COSV65665157; ClinVar: uncertain significance; called by mutect2, varscan2
- COL6A5 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374168010; called by muse, mutect2, varscan2
- COL7A1 | c.5097G>A p.P1699= | Splice Region (SNP) | VAF 67/308 reads (22%) | catalogued as rs369034739, CS993004; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO6 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 75/366 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs751078194, COSV100801460; called by muse, mutect2, varscan2
- COX6B2 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 97/559 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1427357013; called by muse, mutect2, varscan2
- CPA5 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs527363218; called by muse, mutect2, varscan2
- CPED1 | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs1376326632; called by muse, mutect2, varscan2
- CROCC2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 96/543 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs536133683, COSV70368667; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 40/192 reads (21%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRYGC | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 84/456 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs141474796; called by muse, mutect2, varscan2
- CSAD | c.181C>T p.R61W (on ENST00000444623 / NM_001244705.2; = p.R88W on NM_015989.5) | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1323083299, COSV57243886; called by muse, mutect2, varscan2
- CSMD1 | c.1771G>A p.A591T (on ENST00000520002; = p.A590T on NM_033225.6) | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs760676263, COSV59406389; called by muse, mutect2, varscan2
- CSMD2 | c.7745G>A p.R2582H | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs756422988, COSV104385321; called by muse, mutect2, varscan2
- CT47B1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.914); catalogued as rs756748294, COSV100989014; called by muse, mutect2, varscan2
- CYP4A11 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs148717576, COSV60222126; called by muse, mutect2, varscan2
- DCHS1 | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 159/681 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV55033288; called by muse, mutect2, varscan2
- DCHS1 | c.3415C>T p.R1139C | Missense Mutation (SNP) | VAF 89/425 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757309797, CM161949; called by muse, mutect2, varscan2
- DDIT4 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 101/504 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100259180; called by muse, mutect2, varscan2
- DDX60 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs370438683; called by muse, mutect2, varscan2
- DEF6 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100359588; called by mutect2, varscan2
- DEFB110 | c.20del p.F7Sfs*25 | Frame Shift Del (DEL) | VAF 49/219 reads (22%) | catalogued as rs772119246; called by mutect2, pindel, varscan2
- DENND11 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 110/567 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752177264, COSV72097741; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 44/218 reads (20%) | catalogued as rs373108427; called by mutect2, varscan2
- DIP2A | c.3854G>A p.R1285Q | Missense Mutation (SNP) | VAF 73/400 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1378986403; called by muse, mutect2, varscan2
- DISP3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 110/551 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.041); catalogued as rs775340904, COSV53833250; called by muse, mutect2, varscan2
- DMBT1 | c.7604dup p.R2536Tfs*79 (on ENST00000338354 / NM_001377530.1; = p.R1779Tfs*79 on NM_004406.3) | Frame Shift Ins (INS) | VAF 49/318 reads (15%) | catalogued as rs758466994; called by mutect2, varscan2
- DNAH17 | c.8911C>T p.R2971C | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs755460471; called by muse, mutect2, varscan2
- DNAH5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs757056449, CM150542, COSV54237241; called by muse, mutect2, varscan2
- DNAH9 | c.4783G>A p.D1595N | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs780836548, COSV52365436; called by muse, mutect2, varscan2
- DNAI3 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs12029771; called by muse, mutect2, varscan2
- DNAJB2 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 109/525 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs755166275, COSV55346874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNHD1 | c.11488C>T p.R3830C | Missense Mutation (SNP) | VAF 50/504 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs998065768; called by muse, mutect2
- DOCK3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs761053993; called by muse, mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 47/288 reads (16%) | catalogued as rs1239294263; called by mutect2, pindel, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 57/238 reads (24%) | catalogued as rs748560644; called by mutect2, pindel, varscan2
- DPYS | c.1171A>G p.R391G | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV59826759, COSV59826868, COSV59826998; called by muse, mutect2, varscan2
- DPYSL5 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 63/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs750067918, COSV56514942; called by muse, mutect2, varscan2
- DROSHA | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs778322623; called by muse, mutect2, varscan2
- DST | c.21553C>T p.R7185* (on ENST00000361203 / NM_001374722.1; = p.R4882* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 44/217 reads (20%) | catalogued as rs758542461; called by muse, mutect2, varscan2
- DUOX2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 154/746 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as rs539668767; called by muse, mutect2, varscan2
- DVL1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 92/507 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs1021940894, COSV66680148; called by muse, mutect2, varscan2
- DYNC1I1 | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1033384038; called by muse, mutect2, varscan2
- DYNC2H1 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745436653, COSV100519421; called by muse, mutect2, varscan2
- DZIP1 | c.144dup p.S49Qfs*156 | Frame Shift Ins (INS) | VAF 109/674 reads (16%) | catalogued as rs747750483; called by mutect2, pindel, varscan2
- ECHDC2 | c.583C>T p.R195* (on ENST00000371522 / NM_001198961.2; = p.R164* on NM_018281.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 109/523 reads (21%) | catalogued as rs376450584; called by muse, mutect2, varscan2
- EGFLAM | c.2854C>A p.P952T (on ENST00000354891 / NM_001205301.2; = p.P944T on NM_152403.4) | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59299493; called by muse, mutect2, varscan2
- EIF4G1 | c.1305del p.T436Pfs*86 (on ENST00000346169 / NM_198241.3; = p.T240Pfs*86 on NM_004953.5) | Frame Shift Del (DEL) | VAF 83/547 reads (15%) | catalogued as COSV104407217; called by mutect2, pindel, varscan2
- EIF5 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99384750; called by muse, mutect2, varscan2
- ELAC1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 109/495 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs373421001; called by muse, mutect2, varscan2
- ELF4 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs369991603; called by muse, mutect2, varscan2
- ENC1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394470121; called by muse, mutect2
- ENGASE | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs371519373; called by muse, mutect2, varscan2
- EPB41L3 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs935184617, COSV59454852; called by muse, mutect2, varscan2
- EPHB2 | c.2927C>T p.A976V (on ENST00000400191 / NM_001309193.2; = p.A977V on NM_004442.7) | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs1030955500, COSV101006940; called by muse, mutect2, varscan2
- EPPK1 | c.6158G>A p.R2053Q | Missense Mutation (SNP) | VAF 116/641 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.933); catalogued as rs782452886; called by muse, mutect2, varscan2
- EPS8L2 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 123/561 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs11555483; called by muse, mutect2, varscan2
- ERBB4 | c.2363T>C p.L788P | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100728528; called by muse, mutect2, varscan2
- EVX1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 99/546 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.253); catalogued as rs767858813; called by muse, mutect2, varscan2
- EXTL3 | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs774554716, COSV99594463; called by muse, mutect2, varscan2
- FAM135B | c.1169del p.P390Rfs*18 | Frame Shift Del (DEL) | VAF 86/494 reads (17%) | catalogued as COSV52744495, COSV52754574, COSV52759780; called by mutect2, pindel, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 132/685 reads (19%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM47B | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1209259469, COSV61454876; called by muse, mutect2, varscan2
- FAM53C | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs747747219, COSV53511290; called by muse, mutect2, varscan2
- FANCB | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1366041068; ClinVar: uncertain significance; called by muse, mutect2
- FAT3 | c.11200C>T p.R3734C | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs373525308; called by muse, mutect2, varscan2
- FBLN2 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as rs557670680; called by muse, mutect2
- FBN2 | c.8423A>G p.N2808S | Missense Mutation (SNP) | VAF 86/404 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs772227931, COSV52505558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBRSL1 | c.3004dup p.L1002Pfs*67 | Frame Shift Ins (INS) | VAF 38/168 reads (23%) | catalogued as rs1207520184; called by mutect2, varscan2
- FBXO10 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 91/489 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs111810677, COSV99446346; called by muse, mutect2, varscan2
- FER1L6 | c.3709G>A p.G1237S | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV101206146; called by muse, mutect2, varscan2
- FER1L6 | c.4058C>A p.P1353H | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99065104; called by muse, mutect2, varscan2
- FEZF2 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 106/588 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs781518829; called by muse, mutect2, varscan2
- FGD5 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 98/509 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs552194479; called by muse, mutect2, varscan2
- FGF12 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 108/537 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1239358277, COSV53160176; called by muse, mutect2, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 39/243 reads (16%) | catalogued as rs35667286; called by mutect2, pindel, varscan2
- FHOD3 | c.4001G>A p.R1334H (on ENST00000359247 / NM_001281739.3; = p.R1351H on NM_025135.5) | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs775735689, COSV57166173; called by muse, mutect2, varscan2
- FILIP1L | c.2822C>T p.T941M (on ENST00000354552 / NM_182909.3; = p.T701M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/405 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.475); catalogued as rs374858996, COSV58771156; called by muse, mutect2, varscan2
- FIP1L1 | c.781_783del p.P261del | In Frame Del (DEL) | VAF 35/249 reads (14%) | catalogued as rs779469853; called by pindel, varscan2
- FKBP15 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749402432, COSV53040081; called by muse, mutect2, varscan2
- FLG | c.3536C>A p.S1179Y | Missense Mutation (SNP) | VAF 140/656 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV64236023; called by muse, mutect2
- FOXG1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57396872; called by muse, mutect2, varscan2
- FOXJ1 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs778173571; called by muse, varscan2
- FOXP2 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.127); catalogued as rs1254975807; called by muse, mutect2, varscan2
- FRAS1 | c.7844C>T p.A2615V | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs770933194; called by muse, mutect2, varscan2
- FREM1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 78/437 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs573357415, COSV66517690, COSV66528172; called by muse, mutect2, varscan2
- FREM2 | c.6524T>C p.M2175T | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1390505886; called by muse, mutect2, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 102/462 reads (22%) | catalogued as rs765771244; called by mutect2, varscan2
- FUBP3 | c.1184dup p.P396Sfs*28 | Frame Shift Ins (INS) | VAF 112/546 reads (21%) | catalogued as rs751337571; called by mutect2, pindel, varscan2
- GDF10 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 146/668 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs782792166; called by muse, mutect2, varscan2
- GDF6 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs1451309614; called by muse, mutect2, varscan2
- GIMAP1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 135/669 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs1199808162; called by muse, mutect2, varscan2
- GLDC | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as CM1412002, COSV58683511; called by muse, mutect2, varscan2
- GLG1 | c.2115C>T p.H705= | Splice Region (SNP) | VAF 60/309 reads (19%) | catalogued as rs917144767; called by muse, mutect2, varscan2
- GLT1D1 | c.290del p.N97Tfs*21 | Frame Shift Del (DEL) | VAF 54/266 reads (20%) | catalogued as rs769605828, COSV55878296; called by mutect2, pindel, varscan2
- GMIP | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 302/842 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV99179301; called by muse, mutect2, varscan2
- GNAL | c.1118T>C p.M373T (on ENST00000269162 / NM_001142339.3; = p.M450T on NM_182978.4) | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1449657115; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 137/572 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV61476400; called by mutect2, varscan2
- GPR82 | c.142dup p.T48Nfs*88 | Frame Shift Ins (INS) | VAF 78/192 reads (41%) | catalogued as rs765876009; called by mutect2, varscan2
- GPT | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 101/615 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs1487980337; called by muse, mutect2, varscan2
- GRIK1 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs758438478, COSV58716496; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 41/196 reads (21%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 104/378 reads (28%) | catalogued as COSV58051797; called by mutect2, varscan2
- GRK7 | c.16del p.A6Pfs*5 | Frame Shift Del (DEL) | VAF 68/409 reads (17%) | catalogued as COSV99380338; called by pindel, varscan2
- GRK7 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 110/565 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1051988672, COSV53823235; called by muse, varscan2
- GRWD1 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 120/646 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99474293; called by muse, varscan2
- GSX2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 84/511 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs773302954, COSV58842861; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 52/228 reads (23%) | catalogued as rs750792116; called by mutect2, varscan2
- GUCY1B1 | c.1397A>C p.N466T | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52377762; called by muse, mutect2, varscan2
- GUCY2D | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 92/487 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.054); catalogued as rs1485169567; called by muse, mutect2, varscan2
- GUF1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs35318223; called by muse, varscan2
- GUK1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558112580; called by muse, mutect2, varscan2
- GYG1 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 70/367 reads (19%) | catalogued as COSV56048995; called by muse, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 78/356 reads (22%) | catalogued as COSV52242263; called by mutect2, varscan2
- HDHD5 | c.678del p.Y227Tfs*7 (on ENST00000336737 / NM_033070.3; = p.Y197Tfs*7 on NM_017829.5) | Frame Shift Del (DEL) | VAF 111/553 reads (20%) | catalogued as rs760251393; called by mutect2, pindel, varscan2
- HDLBP | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs756644872; called by muse, varscan2
- HEXIM2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 71/430 reads (17%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV56236732; called by muse, mutect2, varscan2
- HGFAC | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 95/442 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs774763627, COSV58750566, COSV58751474; called by muse, varscan2
- HGS | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 90/453 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs749317305, COSV61266631; called by muse, mutect2, varscan2
- HIRIP3 | c.136_138del p.E46del | In Frame Del (DEL) | VAF 78/427 reads (18%) | catalogued as rs771608969; called by pindel, varscan2
- HOOK2 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs377311315; called by muse, mutect2, varscan2
- HOXC13 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 113/506 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs759565446, COSV54498442; called by muse, varscan2
- HOXD1 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 107/515 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.188); catalogued as rs144268439; called by muse, mutect2, varscan2
- HPD | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774901499, COSV56641146; called by muse, mutect2, varscan2
- HPD | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1415357723; called by muse, mutect2
- HPN | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 229/613 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV52884943; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 71/274 reads (26%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- HSPG2 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 60/302 reads (20%) | catalogued as rs1332584154, COSV65930008; called by muse, varscan2
- HTR6 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 123/625 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as rs887205866, COSV53876099; called by muse, mutect2, varscan2
- IDUA | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs1375839111, COSV56107118; called by muse, varscan2
- IFI16 | c.252del p.E85Kfs*3 | Frame Shift Del (DEL) | VAF 35/231 reads (15%) | catalogued as rs1557862995; called by mutect2, pindel, varscan2
- IFT172 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs561676433, COSV99561700; called by muse, mutect2, varscan2
- IGF2BP1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs1332823704; called by muse, mutect2, varscan2
- IGKV1D-13 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs777852760; called by muse, mutect2, varscan2
- IL11 | c.509del p.G170Afs*14 | Frame Shift Del (DEL) | VAF 130/873 reads (15%) | catalogued as rs1362559161; called by mutect2, pindel, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 78/416 reads (19%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INF2 | c.1415dup p.A473Sfs*13 | Frame Shift Ins (INS) | VAF 25/132 reads (19%) | catalogued as COSV53035715; called by mutect2, varscan2
- INSYN1 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 91/487 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377764222; called by muse, mutect2, varscan2
- IPPK | c.923del p.N308Tfs*54 | Frame Shift Del (DEL) | VAF 44/288 reads (15%) | catalogued as rs1453203822; called by mutect2, pindel, varscan2
- IRX3 | c.706dup p.E236Gfs*12 | Frame Shift Ins (INS) | VAF 82/454 reads (18%) | catalogued as rs761463912; called by mutect2, varscan2
- ITGAX | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 117/505 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99191977; called by muse, mutect2, varscan2
- ITPR2 | c.7903G>A p.V2635I | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs368039850; called by muse, varscan2
- ITPR3 | c.4264G>A p.V1422M | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1258001076, COSV65412489; called by muse, mutect2, varscan2
- JAK2 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs781669824; called by muse, mutect2, varscan2
- KAT5 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as rs1446258258; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 79/438 reads (18%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNC4 | c.19_20del p.V7Lfs*41 | Frame Shift Del (DEL) | VAF 59/313 reads (19%) | catalogued as rs781774815; called by pindel, varscan2
- KCNG2 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs779090577; called by muse, mutect2, varscan2
- KCNJ12 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 116/798 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145471133; called by muse, varscan2
- KCNK15 | c.797dup p.A268Gfs*94 | Frame Shift Ins (INS) | VAF 124/486 reads (26%) | catalogued as rs768101521; called by mutect2, varscan2
- KCNQ5 | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59671208; called by muse, mutect2, varscan2
- KEAP1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 141/759 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV50260447, COSV50260545; called by muse, mutect2, varscan2
- KIAA0930 | c.876del p.T293Pfs*27 (on ENST00000336156 / NM_001009880.2; = p.T298Pfs*27 on NM_015264.2) | Frame Shift Del (DEL) | VAF 80/448 reads (18%) | catalogued as rs1294718664; called by pindel, varscan2
- KIAA1755 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs564034366, COSV54074724; called by muse, mutect2, varscan2
- KLHL12 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444143449; called by muse, mutect2, varscan2
- KLHL3 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs756804876; called by muse, mutect2, varscan2
- KLK4 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs772066068, COSV60675596; called by muse, mutect2, varscan2
- KMT2C | c.7789C>G p.P2597A | Missense Mutation (SNP) | VAF 101/449 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51450870; called by muse, mutect2, varscan2
- KMT2D | c.15323G>A p.R5108H | Missense Mutation (SNP) | VAF 116/534 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214099522, COSV56423770; called by muse, mutect2, varscan2
- KMT5A | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100389673; called by muse, varscan2
- KPNA2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs369989302; called by muse, mutect2, varscan2
- KRTAP5-4 | c.269del p.G90Afs*148 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | catalogued as rs757054967; called by mutect2, pindel, varscan2
- KSR1 | c.1783G>A p.E595K (on ENST00000644974 / NM_001367810.1; = p.E480K on NM_014238.2) | Missense Mutation (SNP) | VAF 140/637 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs372634021, COSV52032792; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 117/573 reads (20%) | catalogued as rs770565486; called by mutect2, varscan2
- LAMA2 | c.8625del p.A2876Pfs*27 | Frame Shift Del (DEL) | VAF 66/405 reads (16%) | catalogued as COSV70352979; called by mutect2, pindel, varscan2
- LEFTY2 | c.790T>C p.C264R | Missense Mutation (SNP) | VAF 114/569 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545519108, COSV64746366; called by muse, mutect2, varscan2
- LHX5 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 97/422 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV55663681; called by muse, varscan2
- LMNTD2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 114/598 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs892524260; called by muse, mutect2, varscan2
- LMTK3 | c.4131del p.E1378Rfs*106 | Frame Shift Del (DEL) | VAF 84/472 reads (18%) | catalogued as rs758225154; called by mutect2, varscan2
- LOXL2 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 97/566 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs142220945; called by muse, mutect2, varscan2
- LRP3 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 143/805 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as rs990288501; called by muse, mutect2, varscan2
- LRRC53 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.818); catalogued as rs750271140; called by muse, mutect2, varscan2
- LRRC8E | c.1327A>G p.R443G | Missense Mutation (SNP) | VAF 108/628 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs1482248275; called by muse, mutect2, varscan2
- LRRN4 | c.566del p.G189Afs*47 | Frame Shift Del (DEL) | VAF 106/683 reads (16%) | catalogued as rs780053537; called by mutect2, pindel, varscan2
- MAGEB6 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 95/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs369750377, COSV100983734, COSV66873311; called by muse, mutect2, varscan2
- MAGEL2 | c.3326A>G p.K1109R | Missense Mutation (SNP) | VAF 79/464 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.132); catalogued as COSV58565718; called by muse, mutect2, varscan2
- MAGEL2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 114/556 reads (21%) | SIFT deleterious, low confidence (0); catalogued as rs780815292, COSV100046380; called by muse, mutect2, varscan2
- MALRD1 | c.4613T>C p.F1538S | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs770420274; called by muse, mutect2, varscan2
- MB21D2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 105/457 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1443718606; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 30/210 reads (14%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM10 | c.1888C>T p.R630* (on ENST00000484800 / NM_182751.3; = p.R629* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 63/336 reads (19%) | catalogued as rs148160347; called by muse, mutect2, varscan2
- MCTP1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 47/318 reads (15%) | catalogued as rs751396813, COSV56505812; called by muse, mutect2, varscan2
- MDGA1 | c.2510_2512del p.F837del | In Frame Del (DEL) | VAF 52/310 reads (17%) | catalogued as rs1561840621; called by pindel, varscan2
- MDH1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs199844838; called by muse, mutect2, varscan2
- MEF2B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 87/677 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs143400241; called by muse, mutect2, varscan2
- MEGF10 | c.1836G>T p.Q612H | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99174657; called by muse, varscan2
- MEP1A | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV57917992; called by muse, mutect2, varscan2
- MFSD2B | c.586del p.A196Pfs*44 | Frame Shift Del (DEL) | VAF 96/531 reads (18%) | catalogued as rs1558322813; called by mutect2, pindel, varscan2
- MGAT3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 106/475 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57865253; called by muse, mutect2, varscan2
- MGAT4C | c.1174del p.I392Lfs*3 | Frame Shift Del (DEL) | VAF 34/202 reads (17%) | catalogued as rs746398787; called by mutect2, varscan2
- MGAT5 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs141403771; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 129/548 reads (24%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIDEAS | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 116/612 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.173); catalogued as COSV99678615; called by muse, varscan2
- MIDEAS | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 98/519 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs755437495; called by muse, varscan2
- MKX | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs143655800; called by muse, mutect2, varscan2
- MLYCD | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 167/707 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.24); catalogued as rs769983897; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs201521390; called by muse, mutect2, varscan2
- MROH1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 98/582 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs752758353; called by muse, mutect2, varscan2
- MROH5 | c.3623C>T p.T1208M | Missense Mutation (SNP) | VAF 93/542 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs778801891, COSV100267361; called by muse, varscan2
- MSLN | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 115/486 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs761467681, COSV53505368; called by muse, varscan2
- MTSS1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100274945; called by muse, mutect2, varscan2
- MUC12 | c.3322C>T p.R1108C (on ENST00000379442; = p.R965C on NM_001164462.1) | Missense Mutation (SNP) | VAF 134/699 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as rs1488222333; called by muse, mutect2, varscan2
- MX1 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as rs199860719; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 127/601 reads (21%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYCBP2 | c.8576C>T p.T2859M (on ENST00000357337; = p.T2897M on NM_015057.5) | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs772245086; called by muse, mutect2, varscan2
- MYH10 | c.5593G>A p.A1865T | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs191086005; called by muse, mutect2, varscan2
- MYH13 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 63/312 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs146716231; called by muse, mutect2, varscan2
- MYH7B | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV53420069; called by muse, mutect2, varscan2
- MYH7B | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 134/654 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369540637; called by muse, mutect2, varscan2
- MYLK | c.3022G>A p.V1008M | Missense Mutation (SNP) | VAF 76/482 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as rs747305438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK4 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs146436167; called by muse, mutect2, varscan2
- MYO1G | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 90/453 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1349062821, COSV99348502; called by muse, mutect2, varscan2
- MYO9B | c.6068C>T p.A2023V | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs753423984, COSV55726838; called by muse, mutect2, varscan2
- N4BP2 | c.574del p.S192Lfs*5 | Frame Shift Del (DEL) | VAF 42/254 reads (17%) | catalogued as rs1560593660; called by mutect2, pindel, varscan2
- NAALADL2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1445171849, COSV71987032; called by muse, mutect2, varscan2
- NACAD | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 90/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101512075, COSV71989544; called by muse, mutect2, varscan2
- NCAM2 | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); catalogued as rs537718470; called by muse, mutect2, varscan2
- NDE1 | c.238_240del p.X80_splice | Splice Site (DEL) | VAF 65/331 reads (20%) | catalogued as rs797045733; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NFE2L3 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 153/702 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs765286795; called by muse, mutect2, varscan2
- NGLY1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99770884; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 64/365 reads (18%) | catalogued as rs1171412241, CD054388; called by mutect2, varscan2
- NKX1-2 | c.250del p.L84Wfs*31 | Frame Shift Del (DEL) | VAF 117/580 reads (20%) | catalogued as rs1554873967; called by mutect2, pindel, varscan2
- NKX2-6 | c.30del p.F11Sfs*34 | Frame Shift Del (DEL) | VAF 62/439 reads (14%) | catalogued as COSV100273957; called by mutect2, pindel, varscan2
- NLRP6 | c.866del p.G289Afs*20 | Frame Shift Del (DEL) | VAF 101/630 reads (16%) | catalogued as rs771837860; called by mutect2, pindel, varscan2
- NOM1 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs1016863571; called by muse, varscan2
- NOP58 | c.1571dup p.R525Efs*35 | Frame Shift Ins (INS) | VAF 49/265 reads (18%) | catalogued as rs769985110; called by mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 71/482 reads (15%) | catalogued as rs746543323; called by mutect2, pindel, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 88/490 reads (18%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH1 | c.5272C>T p.R1758C | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777859108, COSV53032734, COSV99491200; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 102/419 reads (24%) | catalogued as rs765756993; called by mutect2, varscan2
- NR1I2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV61979836; called by muse, mutect2, varscan2
- NRAP | c.4132G>A p.D1378N (on ENST00000359988 / NM_001322945.2; = p.D1343N on NM_006175.4) | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.018); catalogued as rs766526192; called by muse, varscan2
- NRXN1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV68035502; called by muse, varscan2
- NRXN2 | c.3965C>T p.A1322V | Missense Mutation (SNP) | VAF 134/587 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs375639642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP214 | c.6073G>A p.G2025R | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372915209; called by muse, mutect2, varscan2
- NXPH3 | c.453del p.S152Vfs*4 | Frame Shift Del (DEL) | VAF 92/490 reads (19%) | catalogued as COSV60872064; called by mutect2, pindel, varscan2
- OBSCN | c.17020del p.A5674Pfs*21 | Frame Shift Del (DEL) | VAF 59/385 reads (15%) | catalogued as rs757737800; called by mutect2, pindel, varscan2
- OBSL1 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 115/555 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as COSV99217524; called by muse, mutect2, varscan2
- OCA2 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs577826548; called by muse, mutect2, varscan2
- ODF2 | c.310C>T p.R104W (on ENST00000434106 / NM_153433.2; = p.R80W on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410026270; called by muse, mutect2, varscan2
- OR10Z1 | c.664T>G p.L222V | Missense Mutation (SNP) | VAF 66/369 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.03); catalogued as COSV63524121, COSV63525670; called by muse, mutect2, varscan2
- OR1N1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 105/413 reads (25%) | catalogued as rs563253378, COSV59195166; called by muse, mutect2, varscan2
- OR1Q1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs756129489, COSV52917127; called by muse, mutect2, varscan2
- OR52E2 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs267602936, COSV58611784; called by muse, mutect2, varscan2
- OR52W1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 91/492 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756662426, COSV60950726; called by muse, mutect2, varscan2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 64/331 reads (19%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR6X1 | c.4A>G p.R2G | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV60009990; called by muse, varscan2
- OR8H2 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57946052; called by muse, mutect2, varscan2
- OTUD6A | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs763323054; called by muse, mutect2, varscan2
- PACS2 | c.252dup p.S85Qfs*57 | Frame Shift Ins (INS) | VAF 54/329 reads (16%) | catalogued as rs782816086; called by mutect2, pindel, varscan2
- PAGE2B | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV66611328; called by muse, mutect2, varscan2
- PALB2 | c.2743G>A p.A915T | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374736398; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PARD3 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 37/241 reads (15%) | catalogued as COSV60751339; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 66/346 reads (19%) | catalogued as rs756801119; called by mutect2, varscan2
- PBRM1 | c.4525A>G p.S1509G (on ENST00000296302 / NM_001366071.2; = p.S1402G on NM_018313.5) | Missense Mutation (SNP) | VAF 95/501 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs761386514; called by muse, mutect2, varscan2
- PBX2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 86/471 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745957488; called by muse, mutect2, varscan2
- PCDH15 | c.5549C>T p.T1850I | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100226398; called by muse, mutect2, varscan2
- PCDH9 | c.3205G>A p.G1069R (on ENST00000377865 / NM_203487.3; = p.G1035R on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.499); catalogued as COSV60591143; called by muse, mutect2, varscan2
- PCDHA5 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as rs782009759; called by muse, mutect2, varscan2
- PCDHB14 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 129/663 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.185); catalogued as rs145800994; called by muse, mutect2, varscan2
- PCDHB4 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 145/805 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs1554274624; called by muse, mutect2, varscan2
- PCDHGA6 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs745786041, COSV54003399; called by muse, mutect2, varscan2
- PCNX1 | c.6076A>G p.I2026V | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs774102527; called by muse, mutect2, varscan2
- PCSK5 | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs772557782; called by muse, mutect2
- PDE11A | c.2416A>G p.I806V | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs549357707; called by muse, mutect2, varscan2
- PDE7A | c.1303A>G p.R435G (on ENST00000401827 / NM_001242318.3; = p.R409G on NM_002603.4) | Missense Mutation (SNP) | VAF 92/533 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.144); catalogued as rs757381959; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 52/267 reads (19%) | catalogued as rs925772654; called by mutect2, pindel, varscan2
- PIK3CA | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.38); catalogued as COSV99835178; called by muse, mutect2, varscan2
- PIP4K2C | c.393dup p.S132Qfs*4 | Frame Shift Ins (INS) | VAF 49/264 reads (19%) | catalogued as rs750999963; called by mutect2, varscan2
- PITPNM1 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as rs568512246, COSV56874426; called by muse, mutect2, varscan2
- PKHD1 | c.2906C>T p.T969M | Missense Mutation (SNP) | VAF 79/420 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs530600526; called by muse, mutect2, varscan2
- PKHD1L1 | c.6563dup p.S2190Ifs*39 | Frame Shift Ins (INS) | VAF 47/351 reads (13%) | catalogued as rs772426616; called by mutect2, varscan2
- PKNOX2 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 73/335 reads (22%) | catalogued as rs545472680; called by muse, mutect2, varscan2
- PLCH2 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 138/695 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs146955653; called by muse, mutect2, varscan2
- PLEKHF1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 106/605 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs139410556; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 92/513 reads (18%) | catalogued as rs778393033; called by mutect2, varscan2
- PLIN4 | c.2164G>A p.G722R (on ENST00000301286; = p.G737R on NM_001367868.2) | Missense Mutation (SNP) | VAF 95/748 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs374438181; called by muse, varscan2
- PLRG1 | c.543del p.A182Pfs*47 | Frame Shift Del (DEL) | VAF 53/291 reads (18%) | catalogued as COSV57423801; called by mutect2, pindel, varscan2
- PLXNA1 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 106/490 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs769023960; called by muse, mutect2, varscan2
- PLXNA3 | c.5458G>A p.D1820N | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs782094886, COSV63755301; called by muse, mutect2, varscan2
- PNMA8B | c.1114dup p.L372Pfs*13 | Frame Shift Ins (INS) | VAF 90/733 reads (12%) | catalogued as rs1568617504; called by mutect2, pindel, varscan2
- PNPLA1 | c.1180C>T p.P394S (on ENST00000394571 / NM_001374623.1; = p.P299S on NM_173676.2) | Missense Mutation (SNP) | VAF 94/513 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV57236031; called by muse, mutect2, varscan2
- PNPLA7 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs756422524, COSV52999350; called by muse, mutect2, varscan2
- PNPLA8 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs768181060, COSV57551689; called by muse, mutect2, varscan2
- POLRMT | c.2681C>T p.T894M | Missense Mutation (SNP) | VAF 174/588 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs988161909, COSV52116650, COSV99241527; called by muse, mutect2, varscan2
- PON3 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55698821; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 81/429 reads (19%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 48/218 reads (22%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP2R5A | c.498_500del p.F166del | In Frame Del (DEL) | VAF 49/193 reads (25%) | catalogued as rs1254447718; called by pindel, varscan2
- PPP6R3 | c.2302G>A p.A768T (on ENST00000393800 / NM_001352375.2; = p.A688T on NM_018312.5) | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1419315086, COSV55729778, COSV55733362; called by muse, mutect2, varscan2
- PRAG1 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 113/671 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV58162580; called by muse, mutect2, varscan2
- PRAM1 | c.1056del p.P353Hfs*125 | Frame Shift Del (DEL) | VAF 213/767 reads (28%) | catalogued as rs1400310861; called by mutect2, pindel, varscan2
- PRDM10 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772879177; called by muse, mutect2, varscan2
- PRPF39 | c.933T>G p.H311Q | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV99053912; called by muse, mutect2, varscan2
- PRPF4B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as rs780716502, COSV61784093; called by muse, mutect2, varscan2
- PRSS12 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 85/417 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs780352056, COSV56606318; called by muse, mutect2, varscan2
- PRSS8 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 94/473 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as rs368523772; called by muse, mutect2, varscan2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 90/375 reads (24%) | catalogued as rs761494960; called by mutect2, pindel, varscan2
- PTAR1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61209761; called by muse, mutect2, varscan2
- PTCHD3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 93/506 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.077); catalogued as rs766944711, COSV71256991; called by muse, mutect2, varscan2
- PTCHD4 | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs1282064075; called by muse, mutect2, varscan2
- PTGDS | c.260A>C p.N87T | Missense Mutation (SNP) | VAF 99/475 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV56400637; called by muse, mutect2, varscan2
- PTGES2 | c.1124del p.P375Qfs*? | Frame Shift Del (DEL) | VAF 63/411 reads (15%) | catalogued as COSV52969657; called by mutect2, pindel, varscan2
- PTGFRN | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 160/771 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs1261081440; called by muse, mutect2, varscan2
- PTPRE | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV54546911; called by muse, mutect2, varscan2
- PTPRG | c.2165del p.N722Tfs*5 | Frame Shift Del (DEL) | VAF 51/249 reads (20%) | catalogued as rs869306841; called by mutect2, pindel, varscan2
- PTPRN | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as rs781122952, COSV55346106, COSV99833898; called by muse, varscan2
- PTPRN | c.356del p.P119Qfs*81 | Frame Shift Del (DEL) | VAF 61/292 reads (21%) | catalogued as rs759562798; called by mutect2, pindel, varscan2
- PWWP2A | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 126/668 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1053737386; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 34/190 reads (18%) | catalogued as rs755727862; called by mutect2, varscan2
- QSER1 | c.3482C>A p.P1161H (on ENST00000399302; = p.P1290H on NM_001076786.3) | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67900201; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 114/529 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1270199097; called by muse, varscan2
- RAB20 | c.217dup p.A73Gfs*9 | Frame Shift Ins (INS) | VAF 78/421 reads (19%) | catalogued as rs764727703; called by mutect2, pindel, varscan2
- RAD54L2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995160338; called by muse, mutect2, varscan2
- RANBP3 | c.763G>A p.A255T (on ENST00000340578 / NM_007322.3; = p.A250T on NM_003624.3) | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs201812693; called by muse, mutect2, varscan2
- RAVER2 | c.1952dup p.R652Afs*19 (on ENST00000294428 / NM_001366165.1; = p.R639Afs*19 on NM_018211.4) | Frame Shift Ins (INS) | VAF 41/281 reads (15%) | catalogued as rs1357653200; called by mutect2, pindel, varscan2
- RCOR2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353238538, COSV100036159; called by muse, mutect2, varscan2
- RELN | c.9298A>G p.K3100E | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.904); catalogued as rs1562851452; called by muse, mutect2, varscan2
- RGS12 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747221893, COSV60906398; called by muse, mutect2, varscan2
- RGS20 | c.709G>A p.E237K (on ENST00000297313 / NM_170587.4; = p.E90K on NM_003702.4) | Missense Mutation (SNP) | VAF 61/388 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs770358295; called by muse, mutect2, varscan2
- RHPN1 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 104/576 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.018); catalogued as rs761413309; called by muse, varscan2
- RIC3 | c.326dup p.L109Ffs*9 | Frame Shift Ins (INS) | VAF 50/282 reads (18%) | catalogued as rs746684945; called by mutect2, varscan2
- RNF220 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1191372684, COSV62405377; called by muse, mutect2, varscan2
- ROBO3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240099635; called by muse, mutect2, varscan2
- RPAP1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 60/315 reads (19%) | catalogued as rs1270782764, COSV58540797; called by muse, mutect2, varscan2
- RUBCN | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 96/408 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs898016545; called by muse, mutect2, varscan2
- RUBCNL | c.1679T>C p.L560P | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1057330862; called by muse, mutect2, varscan2
- RUNX1 | c.1069C>G p.P357A (on ENST00000344691 / NM_001001890.3; = p.P384A on NM_001754.5) | Missense Mutation (SNP) | VAF 110/604 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55873338, COSV55892862; called by muse, mutect2, varscan2
- RXRA | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as rs1306245171, COSV62685560; called by muse, mutect2, varscan2
- RXRB | c.874del p.A292Lfs*45 | Frame Shift Del (DEL) | VAF 96/488 reads (20%) | catalogued as COSV100553958; called by mutect2, pindel, varscan2
- RYR1 | c.5282G>A p.G1761D | Missense Mutation (SNP) | VAF 122/606 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1568484785; called by muse, varscan2
- RYR2 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.919); catalogued as rs754312807, COSV63684032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 90/427 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs11542632, COSV100541474; called by muse, mutect2, varscan2
- S1PR1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs138199836; called by muse, mutect2, varscan2
- S1PR4 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 233/753 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200975604; called by muse, mutect2, varscan2
- SAFB | c.2348G>A p.R783H | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs368894379; called by muse, mutect2, varscan2
- SALL4 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 109/503 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53851362; called by muse, mutect2, varscan2
- SCAF1 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 142/729 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs755053439; called by muse, mutect2, varscan2
- SCCPDH | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as rs763724709; called by muse, mutect2, varscan2
- SCIN | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs949283545; called by muse, mutect2, varscan2
- SCN7A | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs780347946; called by muse, mutect2, varscan2
- SCN8A | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.37); catalogued as rs756127631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRN2 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 108/407 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs374214556; called by muse, mutect2, varscan2
- SCUBE1 | c.2252C>A p.T751N | Missense Mutation (SNP) | VAF 90/421 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100683720; called by mutect2, varscan2
- SDHAF3 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); catalogued as rs952997466; called by muse, mutect2, varscan2
- SDK1 | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs773030910; called by muse, varscan2
- SELENON | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs771563318, COSV62525525; called by muse, mutect2, varscan2
- SEMA4B | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs775685470, COSV60173820; called by muse, mutect2, varscan2
- SEPTIN2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 80/347 reads (23%) | catalogued as rs1203923755; called by muse, mutect2, varscan2
- SERPINB4 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 95/449 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.288); catalogued as rs367838172; called by muse, mutect2, varscan2
- SERPIND1 | c.1150dup p.S384Kfs*36 | Frame Shift Ins (INS) | VAF 53/315 reads (17%) | catalogued as rs1393110462; called by mutect2, pindel, varscan2
- SETBP1 | c.3196T>C p.Y1066H | Missense Mutation (SNP) | VAF 86/452 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99953186; called by muse, mutect2, varscan2
- SETD1A | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs976305904; called by muse, mutect2, varscan2
- SFMBT2 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62807860; called by muse, mutect2, varscan2
- SGIP1 | c.559A>C p.S187R | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV52766532; called by muse, mutect2, varscan2
- SGSM1 | c.2156G>A p.R719H (on ENST00000400359 / NM_001039948.4; = p.R658H on NM_133454.3) | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.354); catalogued as rs555869365; called by muse, mutect2, varscan2
- SH3BP5L | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV63539493; called by muse, mutect2, varscan2
- SH3TC1 | c.1645del p.A549Rfs*51 | Frame Shift Del (DEL) | VAF 98/550 reads (18%) | catalogued as COSV55286810; called by mutect2, pindel, varscan2
- SHISA7 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 113/681 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100890803; called by mutect2, varscan2
- SHROOM3 | c.3002del p.P1001Lfs*11 | Frame Shift Del (DEL) | VAF 162/718 reads (23%) | catalogued as COSV56024643; called by mutect2, pindel, varscan2
- SIK3 | c.2446C>T p.R816C (on ENST00000445177 / NM_001366686.2; = p.R774C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs771368681; called by muse, mutect2, varscan2
- SIPA1L1 | c.5318G>A p.R1773Q | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1448517583; called by muse, mutect2, varscan2
- SIRT2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs146760070; called by muse, mutect2, varscan2
- SIRT5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs139920526; called by muse, mutect2, varscan2
- SLAIN1 | c.676T>C p.S226P (on ENST00000466548; = p.S84P on NM_001040153.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs751507303; called by muse, mutect2, varscan2
- SLC10A2 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as rs144135132; ClinVar: uncertain significance; called by muse, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 54/236 reads (23%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC25A18 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 60/400 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.473); catalogued as rs775428066, COSV53657941; called by muse, mutect2, varscan2
- SLC33A1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 91/429 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63946772; called by muse, mutect2, varscan2
- SLC38A1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs1387383265, COSV67064073; called by muse, mutect2, varscan2
- SLC3A1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs553710376, COSV53222765; called by muse, mutect2, varscan2
- SLC41A2 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51605552; called by muse, mutect2, varscan2
- SLC4A3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 78/386 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as rs974136677; called by mutect2, varscan2
- SLC4A3 | c.3108dup p.L1037Afs*35 | Frame Shift Ins (INS) | VAF 116/561 reads (21%) | catalogued as rs757961785; called by mutect2, varscan2
- SLC6A1 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55117685; called by muse, mutect2, varscan2
- SLC6A7 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs751828376, COSV57939290; called by muse, mutect2, varscan2
- SLITRK1 | c.134del p.K45Rfs*64 | Frame Shift Del (DEL) | VAF 73/338 reads (22%) | catalogued as COSV65676896; called by mutect2, pindel, varscan2
- SMARCAL1 | c.2452G>A p.V818M | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759861726, COSV61920257; called by muse, mutect2, varscan2
- SMG5 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 105/491 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1325455711; called by muse, mutect2, varscan2
- SNX11 | c.133A>G p.N45D | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63658888; called by muse, mutect2, varscan2
- SNX15 | c.352del p.Q118Sfs*11 | Frame Shift Del (DEL) | VAF 86/414 reads (21%) | catalogued as rs1228498607; called by mutect2, pindel, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 101/580 reads (17%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 48/224 reads (21%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SP9 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 104/560 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV67602321; called by muse, mutect2, varscan2
- SPANXN3 | c.71del p.N24Mfs*12 | Frame Shift Del (DEL) | VAF 60/129 reads (47%) | catalogued as rs781940283; called by mutect2, varscan2
- SPARCL1 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.453); catalogued as rs747673173, COSV99215693; called by muse, mutect2, varscan2
- SPECC1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 81/444 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs771834650, COSV54952341; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 57/240 reads (24%) | catalogued as rs748467821; called by mutect2, varscan2
- SRGAP3 | c.2548dup p.V850Gfs*10 | Frame Shift Ins (INS) | VAF 58/339 reads (17%) | catalogued as rs759698239; called by mutect2, varscan2
- SRGAP3 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 63/387 reads (16%) | catalogued as COSV64536141; called by muse, mutect2, varscan2
- SSBP2 | c.152del p.N51Tfs*54 | Frame Shift Del (DEL) | VAF 62/280 reads (22%) | catalogued as rs1057518330; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ST8SIA6 | c.14del p.G5Afs*47 | Frame Shift Del (DEL) | VAF 44/285 reads (15%) | catalogued as rs1394686873; called by pindel, varscan2
- STAC | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1419991634, COSV56217028, COSV99830019; called by muse, mutect2, varscan2
- STPG2 | c.611del p.K204Rfs*6 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | catalogued as rs778953320; called by mutect2, varscan2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 119/441 reads (27%) | catalogued as rs762120842, COSV51992441; called by mutect2, varscan2
- STRAP | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs752651730, COSV99214598; called by muse, mutect2, varscan2
- STX11 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 124/576 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV62448525; called by muse, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 28/160 reads (18%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPT5H | c.2452A>G p.S818G | Missense Mutation (SNP) | VAF 161/788 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs950251547, COSV63240203; called by muse, mutect2, varscan2
- SYCP1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1386321751, COSV101050990, COSV65701267; called by muse, mutect2, varscan2
- SYCP1 | c.2642del p.K881Rfs*21 | Frame Shift Del (DEL) | VAF 34/206 reads (17%) | catalogued as rs776683356; called by mutect2, varscan2
- SYNDIG1 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 104/506 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778879994; called by muse, varscan2
- SYNGAP1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 125/595 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770063012, COSV53383124, COSV99537897; called by muse, mutect2, varscan2
- TACC2 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 111/519 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142141564; called by muse, mutect2, varscan2
- TAF11L13 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 75/376 reads (20%) | catalogued as rs1354124115; called by muse, mutect2, varscan2
- TARBP1 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs551311836, COSV50211809; called by muse, mutect2
- TBC1D10A | c.518dup p.H174Pfs*40 | Frame Shift Ins (INS) | VAF 61/270 reads (23%) | catalogued as rs772995689; called by mutect2, varscan2
- TBC1D16 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 140/599 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs761831801; called by muse, mutect2, varscan2
- TBC1D17 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 70/463 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs372112489; called by muse, mutect2, varscan2
- TBKBP1 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442310303, COSV64653380; called by muse, mutect2, varscan2
- TBX22 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs993952750, COSV64785489; called by muse, mutect2, varscan2
- TCF15 | c.571del p.V191Wfs*40 | Frame Shift Del (DEL) | VAF 66/378 reads (17%) | catalogued as rs1188135918; called by mutect2, varscan2
- TCF3 | c.1068del p.V357Wfs*37 | Frame Shift Del (DEL) | VAF 149/513 reads (29%) | catalogued as COSV99514881; called by mutect2, pindel, varscan2
- TCTE1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs112092930, COSV65255064; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 123/372 reads (33%) | catalogued as rs763321097; called by mutect2, varscan2
- TEAD2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200637426; called by muse, mutect2, varscan2
- TENM3 | c.8005G>T p.G2669W | Missense Mutation (SNP) | VAF 87/480 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459830865, COSV69308012; called by muse, mutect2, varscan2
- TENT4A | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs1010085675; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 89/471 reads (19%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TMEM131 | c.2444del p.N815Ifs*2 | Frame Shift Del (DEL) | VAF 48/249 reads (19%) | catalogued as rs1559368991; called by mutect2, varscan2
- TMEM131 | c.2401A>G p.R801G | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs753843601; called by muse, mutect2, varscan2
- TMEM175 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 60/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs561973833; called by muse, mutect2, varscan2
- TMEM200C | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 117/602 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as rs1347076969, COSV101274844; called by muse, mutect2, varscan2
- TMPO | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 79/404 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs771808300; called by muse, mutect2, varscan2
- TMPRSS15 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs186150928, COSV53036570; called by muse, varscan2
- TNFRSF21 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763251574, COSV57286001; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 53/217 reads (24%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNK1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1230890831; called by muse, mutect2, varscan2
- TNR | c.1484del p.P495Lfs*42 | Frame Shift Del (DEL) | VAF 72/359 reads (20%) | catalogued as COSV54899554; called by mutect2, pindel, varscan2
- TONSL | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.915); catalogued as rs1432152447; called by muse, mutect2, varscan2
- TOP1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 93/433 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1171906901, COSV63694790; called by muse, mutect2, varscan2
- TOPORS | c.2708G>T p.R903L | Missense Mutation (SNP) | VAF 81/408 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV62117493; called by muse, mutect2, varscan2
- TP63 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs750962649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAM1L1 | c.36dup p.V13Rfs*92 | Frame Shift Ins (INS) | VAF 57/292 reads (20%) | catalogued as rs753182240; called by mutect2, varscan2
- TRIM6 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.332); catalogued as rs930831268, COSV53474502; called by muse, varscan2
- TRIM64B | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 73/738 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs573755227, COSV61693979; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 29/152 reads (19%) | catalogued as rs780358338; called by mutect2, varscan2
- TRO | c.3163A>G p.T1055A | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); catalogued as rs1299576353; called by muse, mutect2, varscan2
- TRPV4 | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750416252, COSV55681007; called by muse, mutect2, varscan2
- TSPY1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 46/535 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV101369647; called by muse, mutect2, varscan2
- TSPYL5 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 88/509 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV59072714; called by muse, mutect2, varscan2
- TTC28 | c.6527C>T p.A2176V | Missense Mutation (SNP) | VAF 114/486 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs764330777, COSV67416242; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 59/314 reads (19%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTI1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs370340590; called by muse, mutect2, varscan2
- TTN | c.46739G>A p.R15580H (on ENST00000591111; = p.R8156H on NM_003319.4) | Missense Mutation (SNP) | VAF 62/381 reads (16%) | PolyPhen probably damaging (0.998); catalogued as rs770653436, COSV60175619; called by muse, mutect2, varscan2
- TWNK | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1415664013; called by muse, mutect2, varscan2
- UBA6 | c.3023+1G>A p.X1008_splice | Splice Site (SNP) | VAF 45/194 reads (23%) | catalogued as rs768072288; called by muse, mutect2, varscan2
- UBAC1 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1339360847; called by muse, mutect2, varscan2
- UBE3B | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs372827099; called by muse, mutect2, varscan2
- UBL7 | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs995157328; called by muse, mutect2, varscan2
- UBLCP1 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs759938615; called by muse, mutect2, varscan2
- UBXN10 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 66/363 reads (18%) | catalogued as rs747624382, COSV66772318; called by muse, mutect2, varscan2
- UNC13A | c.4203C>T p.I1401= | Splice Region (SNP) | VAF 119/374 reads (32%) | catalogued as rs373253159; called by muse, varscan2
- UNC13A | c.3635A>G p.Q1212R | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV53209032; called by muse, mutect2, varscan2
- UNC80 | c.9386C>T p.A3129V | Missense Mutation (SNP) | VAF 83/434 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); catalogued as rs1488112891; called by muse, mutect2, varscan2
- UNCX | c.1358del p.P453Qfs*89 | Frame Shift Del (DEL) | VAF 42/282 reads (15%) | catalogued as rs1480724225; called by pindel, varscan2
- UROS | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV64223987; called by muse, mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 49/228 reads (21%) | catalogued as rs572063854; called by mutect2, varscan2
- USP45 | c.1580G>A p.G527D | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.091); catalogued as rs771219515; called by muse, mutect2, varscan2
- UST | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 82/512 reads (16%) | catalogued as rs760552029, COSV66551382; called by mutect2, pindel, varscan2
- VAV2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 68/392 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs755033891, COSV64082707; called by muse, mutect2, varscan2
- VPS13B | c.11077G>A p.V3693I | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs746534351, COSV62133728; called by muse, mutect2, varscan2
- WDR6 | c.2421del p.R808Gfs*33 | Frame Shift Del (DEL) | VAF 119/510 reads (23%) | catalogued as rs750038548, COSV58247104; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 48/217 reads (22%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs770002621, COSV60029813; called by muse, varscan2
- WWOX | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs369281766; called by muse, mutect2, varscan2
- XKR4 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 112/510 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59318340; called by muse, mutect2, varscan2
- XKR5 | c.1229T>C p.L410P | Missense Mutation (SNP) | VAF 74/465 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68398994; called by muse, mutect2, varscan2
- XPO5 | c.3544dup p.T1182Nfs*13 | Frame Shift Ins (INS) | VAF 59/328 reads (18%) | catalogued as rs1300130627; called by mutect2, varscan2
- XRCC2 | c.801del p.K267Nfs*30 | Frame Shift Del (DEL) | VAF 46/216 reads (21%) | catalogued as rs759063323; called by mutect2, varscan2
- XRCC5 | c.1532A>T p.H511L | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.168); catalogued as rs775971989; called by muse, mutect2, varscan2
- YY1 | c.690del p.D231Ifs*25 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | catalogued as rs759536629; called by mutect2, varscan2
- ZBTB18 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 106/448 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV62397098; called by muse, mutect2, varscan2
- ZBTB26 | c.67del p.M23* | Frame Shift Del (DEL) | VAF 50/220 reads (23%) | catalogued as COSV101021177; called by mutect2, pindel, varscan2
- ZDHHC11B | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 103/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215423895; called by muse, varscan2
- ZFHX4 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 76/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50927048, COSV51477020; called by muse, varscan2
- ZFHX4 | c.8041C>T p.R2681* | Nonsense Mutation (SNP) | VAF 95/597 reads (16%) | catalogued as COSV50644496, COSV51478684; called by muse, mutect2, varscan2
- ZFP64 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 121/549 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs761296899; called by muse, mutect2, varscan2
- ZFR2 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 105/550 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs766565462; called by muse, mutect2, varscan2
- ZFYVE26 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143078443; called by muse, mutect2, varscan2
- ZMYM3 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1338083779; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 50/276 reads (18%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF345 | c.615A>G p.I205M | Missense Mutation (SNP) | VAF 101/593 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs771168707; called by muse, mutect2, varscan2
- ZNF354A | c.553dup p.T185Nfs*6 | Frame Shift Ins (INS) | VAF 80/404 reads (20%) | catalogued as rs1164748265; called by mutect2, pindel, varscan2
- ZNF449 | c.830dup p.E278Rfs*23 | Frame Shift Ins (INS) | VAF 74/192 reads (39%) | catalogued as rs781874073; called by mutect2, varscan2
- ZNF462 | c.5126G>A p.R1709H | Missense Mutation (SNP) | VAF 86/510 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs773427004, COSV52945829, COSV52953703; called by muse, mutect2, varscan2
- ZNF462 | c.7265C>T p.A2422V | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs781420456; called by muse, varscan2
- ZNF467 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 140/686 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100117904; called by muse, mutect2, varscan2
- ZNF517 | c.390dup p.H131Afs*12 | Frame Shift Ins (INS) | VAF 102/624 reads (16%) | catalogued as rs746799858; called by mutect2, varscan2
- ZNF544 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 67/502 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99516922; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 74/354 reads (21%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF658 | c.801dup p.K268Efs*4 | Frame Shift Ins (INS) | VAF 42/293 reads (14%) | catalogued as rs1191658241; called by mutect2, pindel, varscan2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 46/280 reads (16%) | catalogued as rs781412139; called by mutect2, varscan2
- ZNF831 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 105/535 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs1209000145; called by muse, mutect2, varscan2
- ZSCAN18 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 119/682 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1429150434, COSV53731607; called by muse, mutect2, varscan2
- ZSCAN20 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371224785; called by muse, mutect2
- A4GALT | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 73/357 reads (20%) | called by mutect2, pindel, varscan2
- ABCC6 | c.1589T>G p.L530R | Missense Mutation (SNP) | VAF 124/550 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ABHD14B | c.62T>C p.F21S | Missense Mutation (SNP) | VAF 99/424 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ABR | c.618_629del p.N206_Q209del (on ENST00000302538 / NM_021962.5; = p.N169_Q172del on NM_001092.5) | In Frame Del (DEL) | VAF 38/286 reads (13%) | called by mutect2, pindel, varscan2
- ABRA | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 107/635 reads (17%) | called by muse, mutect2, varscan2
- ABTB1 | c.753del p.E252Sfs*102 (on ENST00000232744 / NM_172027.3; = p.E110Sfs*102 on NM_032548.3) | Frame Shift Del (DEL) | VAF 71/397 reads (18%) | called by mutect2, pindel, varscan2
- ACP4 | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 178/551 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ACTN4 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ADAD2 | c.793G>T p.G265C (on ENST00000315906 / NM_001145400.2; = p.G347C on NM_139174.4) | Missense Mutation (SNP) | VAF 115/592 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS14 | c.1749-1G>A p.X583_splice | Splice Site (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.2728G>T p.A910S | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ADCY3 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ADCY5 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 102/525 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADORA1 | c.929A>G p.Q310R | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADPRHL1 | c.3923C>G p.A1308G | Missense Mutation (SNP) | VAF 100/511 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- AGO4 | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGPAT5 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- AJAP1 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 153/760 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP9 | c.5424G>T p.E1808D (on ENST00000359028; = p.E1776D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AKR7A2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 136/632 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPI | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ALS2CL | c.2696T>C p.L899P | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPT4 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD17 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 146/743 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ANKRD30B | c.4164A>C p.E1388D | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ANKRD7 | c.14dup p.S6Qfs*8 | Frame Shift Ins (INS) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- AP2B1 | c.2612A>G p.N871S | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 38/210 reads (18%) | called by mutect2, varscan2
- AP3B1 | c.2122dup p.E708Gfs*7 | Frame Shift Ins (INS) | VAF 75/408 reads (18%) | called by mutect2, pindel, varscan2
- APBB3 | c.216A>G p.G72= | Splice Region (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- APOBEC4 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.018); called by muse, mutect2
- APOH | c.115del p.T39Hfs*23 | Frame Shift Del (DEL) | VAF 61/390 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP19 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.96); called by muse, varscan2
- ARHGAP26 | c.1649T>C p.I550T | Missense Mutation (SNP) | VAF 62/330 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ARHGAP35 | c.1510dup p.Y504Lfs*2 | Frame Shift Ins (INS) | VAF 117/453 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 83/514 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.879del p.T294Pfs*69 | Frame Shift Del (DEL) | VAF 134/752 reads (18%) | called by mutect2, pindel, varscan2
- ARID1B | c.5508del p.L1837* | Frame Shift Del (DEL) | VAF 109/491 reads (22%) | called by mutect2, pindel, varscan2
- ARSI | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 113/501 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASCC1 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ASIC3 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 69/403 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASTN2 | c.3928T>C p.W1310R (on ENST00000313400 / NM_001365069.1; = p.W1259R on NM_014010.5) | Missense Mutation (SNP) | VAF 94/409 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASXL1 | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 101/489 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- ATP13A2 | c.2393C>T p.T798I | Missense Mutation (SNP) | VAF 94/455 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATP13A2 | c.1212del p.G406Afs*3 | Frame Shift Del (DEL) | VAF 59/390 reads (15%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.84dup p.D29Rfs*6 | Frame Shift Ins (INS) | VAF 54/318 reads (17%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.3023T>C p.I1008T | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ATP8A2 | c.1473dup p.P492Sfs*22 | Frame Shift Ins (INS) | VAF 46/268 reads (17%) | called by mutect2, pindel, varscan2
- ATPAF2 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATRN | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ATXN7 | c.1838del p.P613Qfs*13 | Frame Shift Del (DEL) | VAF 63/421 reads (15%) | called by mutect2, pindel, varscan2
- AUTS2 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 93/505 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- AVL9 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AXIN2 | c.1795del p.A599Pfs*90 | Frame Shift Del (DEL) | VAF 94/498 reads (19%) | called by mutect2, pindel, varscan2
- B4GALNT2 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- B4GALNT3 | c.2266dup p.D756Gfs*6 | Frame Shift Ins (INS) | VAF 93/528 reads (18%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.1149dup p.L384Sfs*120 | Frame Shift Ins (INS) | VAF 66/423 reads (16%) | called by mutect2, pindel, varscan2
- BCL11B | c.1916C>T p.A639V (on ENST00000357195 / NM_001282237.2; = p.A568V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BCL7B | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCL9 | c.209del p.G70Afs*16 | Frame Shift Del (DEL) | VAF 94/597 reads (16%) | called by mutect2, pindel, varscan2
- BEX3 | c.286del p.E96Sfs*23 | Frame Shift Del (DEL) | VAF 95/272 reads (35%) | called by mutect2, pindel, varscan2
- BIRC3 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.388T>G p.L130V | Missense Mutation (SNP) | VAF 93/389 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- BNC2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 62/369 reads (17%) | called by muse, mutect2, varscan2
- BRINP2 | c.2156A>T p.Q719L | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BRINP3 | c.1845dup p.N616Efs*8 | Frame Shift Ins (INS) | VAF 71/434 reads (16%) | called by mutect2, pindel, varscan2
- BRWD3 | c.2333A>T p.Y778F | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD11 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 139/704 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BTBD6 | c.27dup p.S10Qfs*117 | Frame Shift Ins (INS) | VAF 47/187 reads (25%) | called by mutect2, pindel, varscan2
- C19orf54 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 16/580 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- C19orf67 | c.119del p.P40Lfs*60 | Frame Shift Del (DEL) | VAF 262/778 reads (34%) | called by mutect2, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 109/508 reads (21%) | called by mutect2, pindel, varscan2
- C6orf132 | c.1828C>A p.L610I | Missense Mutation (SNP) | VAF 105/546 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C8orf58 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 67/420 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C9orf72 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 78/374 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CABP4 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 75/378 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CADPS2 | c.2741A>G p.N914S | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMKV | c.1044del p.A350Lfs*154 | Frame Shift Del (DEL) | VAF 135/696 reads (19%) | called by mutect2, pindel, varscan2
- CAPN1 | c.1811A>G p.K604R | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.046); called by muse, varscan2
- CAPN5 | c.1091G>A p.W364* (on ENST00000456580; = p.W324* on NM_004055.5) | Nonsense Mutation (SNP) | VAF 72/272 reads (26%) | called by muse, varscan2
- CARMIL3 | c.1856G>T p.R619M | Missense Mutation (SNP) | VAF 65/357 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CASKIN1 | c.1847del p.G616Afs*13 | Frame Shift Del (DEL) | VAF 105/593 reads (18%) | called by mutect2, pindel, varscan2
- CASR | c.1357A>G p.K453E | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CCDC102B | c.1442A>G p.D481G | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC136 | c.2675A>C p.K892T | Missense Mutation (SNP) | VAF 70/386 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC157 | c.2164A>G p.N722D | Missense Mutation (SNP) | VAF 98/585 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CCDC167 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- CCDC168 | c.9895A>G p.T3299A | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CCDC88A | c.4450G>A p.A1484T (on ENST00000436346 / NM_001365480.1; = p.A1483T on NM_001135597.2) | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCNK | c.336del p.K112Nfs*13 | Frame Shift Del (DEL) | VAF 39/245 reads (16%) | called by mutect2, pindel, varscan2
- CCNL1 | c.1061T>A p.I354N | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163L1 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 73/465 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CD300LG | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 119/546 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- CDC42SE2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, varscan2
- CDCA7L | c.998del p.L333* | Frame Shift Del (DEL) | VAF 34/238 reads (14%) | called by mutect2, pindel, varscan2
- CDH1 | c.377dup p.P127Afs*41 | Frame Shift Ins (INS) | VAF 51/317 reads (16%) | called by mutect2, pindel, varscan2
- CDH1 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH16 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 98/506 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDK18 | c.803G>T p.S268I (on ENST00000506784 / NM_212503.3; = p.S238I on NM_002596.4) | Missense Mutation (SNP) | VAF 89/404 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CDK19 | c.1100A>G p.K367R | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CDK9 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 94/415 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CECR2 | c.3557A>G p.N1186S (on ENST00000342247 / NM_001290047.2; = p.N1002S on NM_001290046.1) | Missense Mutation (SNP) | VAF 86/473 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEL | c.2082del p.V695Cfs*12 (on ENST00000673714; = p.V692Cfs*12 on NM_001807.6) | Frame Shift Del (DEL) | VAF 40/163 reads (25%) | called by mutect2, varscan2
- CEP112 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CEP170B | c.2656del p.H886Tfs*28 (on ENST00000453495; = p.H815Tfs*28 on NM_015005.3) | Frame Shift Del (DEL) | VAF 147/826 reads (18%) | called by mutect2, pindel, varscan2
- CERK | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CFAP206 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CFAP65 | c.2414G>A p.C805Y | Missense Mutation (SNP) | VAF 104/497 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CFL1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 70/379 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CHD1 | c.1601dup p.L534Ffs*31 | Frame Shift Ins (INS) | VAF 51/309 reads (17%) | called by mutect2, pindel, varscan2
- CHD3 | c.4062G>T p.Q1354H | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD4 | c.2575G>A p.V859M (on ENST00000357008 / NM_001363606.2; = p.V872M on NM_001273.5) | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CILP2 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 98/622 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIP2A | c.478del p.M160Cfs*4 | Frame Shift Del (DEL) | VAF 30/214 reads (14%) | called by mutect2, pindel, varscan2
- CLCN6 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CLDND1 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CLPB | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 146/660 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNNM2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 107/469 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTRL | c.1856G>A p.S619N | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
1,069 further variants in this file (611 protein-altering or splice-affecting, 393 silent, 65 other) are not listed here.
